Somatic mutation profile of tumor specimen MP2PRT-PASPUH-TMP1-A (aliquot MP2PRT-PASPUH-TMP1-A-1-0-D-A817-36) from MP2PRT case MP2PRT-PASPUH, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.5 years (1,267 days).
Specimen MP2PRT-PASPUH-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8e50b78f-4104-44f9-91bb-f6dda3bce60d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASPUH-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASPUH-NB1-A-1-0-D-A817-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fadd329f-2675-4390-885a-9bf713c9baf7

The open-access MAF lists 16 somatic variants for this specimen: 10 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 8, Silent 6, Nonsense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANOS1 | c.1270C>T p.R424* | Nonsense Mutation (SNP) | VAF 158/655 reads (24%) | catalogued as rs747010865, CD004447, CM040758, COSV52918477; ClinVar: pathogenic; called by muse, mutect2, varscan2
- B4GALT7 | c.176G>A p.R59Q | Missense Mutation (SNP) | VAF 48/512 reads (9%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs1306108840, COSV50352915; called by muse, mutect2
- MECP2 | c.1447G>C p.E483Q | Missense Mutation (SNP) | VAF 56/681 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.405); catalogued as CM132233, COSV57653132; called by muse, mutect2
- RBM46 | c.209G>A p.R70H | Missense Mutation (SNP) | VAF 94/367 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs200425509, COSV55980655; called by muse, mutect2, varscan2
- ROBO2 | c.3913C>T p.R1305* | Nonsense Mutation (SNP) | VAF 102/237 reads (43%) | catalogued as rs1179711497, COSV59895999; called by muse, mutect2, varscan2
- UBB | c.671G>A p.R224H | Missense Mutation (SNP) | VAF 89/234 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.867); catalogued as COSV56218410; called by muse, mutect2, varscan2
- ZNF727 | c.80G>A p.R27H | Missense Mutation (SNP) | VAF 156/369 reads (42%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs1034127441, COSV71646949; called by muse, mutect2, varscan2
- COG8 | c.499C>T p.R167W | Missense Mutation (SNP) | VAF 133/351 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PDLIM1 | c.621T>G p.N207K | Missense Mutation (SNP) | VAF 45/654 reads (7%) | SIFT tolerated (0.92); PolyPhen benign (0.282); called by muse, mutect2
- UHRF1 | c.562T>A p.Y188N (on ENST00000612630 / NM_001290050.1; = p.Y201N on NM_013282.4) | Missense Mutation (SNP) | VAF 100/254 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ARHGAP32 | c.4179G>A p.P1393= (on ENST00000310343 / NM_001378025.1; = p.P1044= on NM_014715.4) | Silent (SNP) | VAF 47/691 reads (7%) | catalogued as rs772807185; called by muse, mutect2
- FAT1 | c.4995G>A p.P1665= | Silent (SNP) | VAF 34/483 reads (7%) | catalogued as rs764593119, COSV101499346; called by muse, mutect2
- FMN2 | c.939G>A p.A313= | Silent (SNP) | VAF 80/698 reads (11%) | catalogued as rs1397777846; called by muse, mutect2, varscan2
- HGSNAT | c.1440C>T p.I480= | Silent (SNP) | VAF 138/389 reads (35%) | catalogued as rs779933668, COSV99925004; called by muse, mutect2, varscan2
- RNF225 | c.648C>T p.G216= | Silent (SNP) | VAF 57/467 reads (12%) | called by muse, mutect2, varscan2
- TMTC2 | c.381C>G p.P127= | Silent (SNP) | VAF 176/352 reads (50%) | called by muse, mutect2, varscan2
